Gene-level copy-number profile of tumor specimen TCGA-EI-6885-01A from TCGA case TCGA-EI-6885, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 57.9 years (21,140 days).
Specimen TCGA-EI-6885-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.09dfc517-90fa-4a08-b574-6e68c21dc2dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EI-6885-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/444c8ad3-59d2-455c-abcf-21f76bc1f4b1

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 78; copy number 2: 8,448; copy number 3: 28,471; copy number 4: 17,074; copy number 5: 1,686; copy number 6: 925; copy number 8: 59; copy number 10: 1,458; copy number 11: 82; copy number 14: 48; copy number 16: 1,485.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EI-6885-01A-11D-1923-01): tumor purity 0.59, ploidy 3.71, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:34,874,159–35,796,550, 6 genes: AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,132 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,585,500–39,949,755, 59 genes, copy number 8: NECAP1P1, GPR141, EPDR1, GPR141BP, AC018634.1, NME8, SFRP4, STARD3NL, TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6, TRG-AS1, TRGV5P, TRGV5, TRGV4, TRGV3, TRGV2, TRGV1, AMPH, RN7SL83P, KRT8P20, FAM183BP, VPS41, POU6F2, POU6F2-AS2, SNORA20B, POU6F2-AS1, AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, AC004837.4, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1.
- chr8:41,032,892–145,066,685, 1,615 genes, copy number 11–16 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 78. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
